Somatic mutation profile of tumor specimen 2d8514b6-c01a-4166-a0c1-bc7012 (aliquot 2d8514b6-c01a-4166-a0c1-bc7012_D6_1) from CPTAC case 03BR012, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 46.4 years (16,942 days).
Specimen 2d8514b6-c01a-4166-a0c1-bc7012: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81c1acf0-df63-4e3e-b50d-a73f11835b86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 52a53fb4-2433-4e65-a5c6-169abe (Blood Derived Normal), aliquot 52a53fb4-2433-4e65-a5c6-169abe_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/284290c4-2539-4660-9caf-615d01e6d8cd

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, Frame Shift Del 3, Intron 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARTN | c.622G>A p.V208M (on ENST00000372354; = p.V216M on NM_057090.2) | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1033109701; called by muse, mutect2, varscan2
- CDK16 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 87/400 reads (22%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.466); catalogued as rs777717613; called by muse, mutect2, varscan2
- PAX8 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 91/430 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as rs752362948; called by muse, mutect2, varscan2
- SDR39U1 | c.474G>A p.G158= | Splice Region (SNP) | VAF 84/347 reads (24%) | catalogued as rs954147244; called by muse, mutect2, varscan2
- AC011005.1 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 154/696 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- KCNQ3 | c.1772T>A p.F591Y | Missense Mutation (SNP) | VAF 75/450 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- KRT9 | c.306del p.G103Efs*47 | Frame Shift Del (DEL) | VAF 23/94 reads (24%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.2056del p.T686Pfs*3 | Frame Shift Del (DEL) | VAF 72/289 reads (25%) | called by mutect2, varscan2
- MAP3K1 | c.2706del p.E903Sfs*6 | Frame Shift Del (DEL) | VAF 58/302 reads (19%) | called by pindel, varscan2
- MEIS3 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TUBB2B | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 91/494 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZYG11B | c.389G>C p.S130T | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- AEBP1 | c.1914C>A p.L638= | Silent (SNP) | VAF 53/266 reads (20%) | catalogued as rs1422593854; called by muse, mutect2, varscan2
- IRAK1 | c.1341G>C p.V447= | Silent (SNP) | VAF 14/231 reads (6%) | called by muse, mutect2
- LSP1 | c.210G>A p.S70= | Silent (SNP) | VAF 51/203 reads (25%) | catalogued as rs768315651, COSV100289115; called by muse, mutect2, varscan2
- MSH6 | c.114C>T p.P38= | Silent (SNP) | VAF 74/259 reads (29%) | catalogued as rs786201700; ClinVar: likely benign; called by muse, mutect2, varscan2
- RFC3 | c.78G>T p.L26= | Silent (SNP) | VAF 5/105 reads (5%) | called by muse, mutect2
- BZW1 | c.-11+428C>T | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as rs953128957; called by muse, mutect2
- NBL1 | c.-20+1580G>A | Intron (SNP) | VAF 22/351 reads (6%) | catalogued as rs1457666423; called by muse, mutect2
